MMRF case MMRF_1700 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/91dadb64-b7bd-430c-91b1-fbf37af9746e

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Dead; Days to death: 569 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.8 years (27,692 days); ISS stage: III; Days to last known disease status: 569 days (1.6 years); Days to last follow up: 569 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 481 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 14 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 19 days; Days to treatment end: 432 days (1.2 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 47 days; Days to treatment end: 194 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 194 days; Days to treatment end: 432 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 439 days (1.2 years); Days to treatment end: 481 days (1.3 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 481 days (1.3 years); Days to treatment end: 559 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 569.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 68.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.48 mg/dL; Immunoglobulin G 39.4 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 6.55 µg/mL; Lactate Dehydrogenase 4.32 µkat/L; Hemoglobin 3.6 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.13 mmol/L; Albumin 27 g/L; Total Protein 10 g/dL; Glucose 6.22 mmol/L; C-Reactive Protein 7.02 mg/dL.
- Day 89 (ECOG 1): M Protein 1.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.38 mg/dL; Immunoglobulin G 18.2 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 7.4 g/dL; Glucose 7.32 mmol/L.
- Day 194 (ECOG 2): M Protein 1.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 18.1 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 7.6 g/dL; Glucose 9.79 mmol/L.
- Day 279 (ECOG 2): M Protein 1.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 211 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.8 mg/dL; Immunoglobulin G 34.1 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 5.33 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 547 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 25 g/L; Total Protein 9.6 g/dL; Glucose 7.1 mmol/L.
- Day 348 (ECOG 2): M Protein 1.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 145 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.69 mg/dL; Immunoglobulin G 25.7 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 583 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.03 mmol/L; Albumin 30 g/L; Total Protein 7.4 g/dL; Glucose 4.68 mmol/L.
- Day 446 (ECOG 1): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 434 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.84 mg/dL; Immunoglobulin G 25.2 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 4.03 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 436 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 27 g/L; Total Protein 7.9 g/dL; Glucose 4.51 mmol/L.
- Day 530: M Protein 3.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 938 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.61 mg/dL; Immunoglobulin G 49.3 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 4.52 µkat/L; Hemoglobin 3.53 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 657 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.15 mmol/L; Albumin 24 g/L; Total Protein 10.6 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day 1: Weight: 90 kg; Height: 173 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1700_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1700_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1700_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 530 days (1.5 years).
